Gene-level copy-number profile of tumor specimen TCGA-DX-AB2S-01A from TCGA case TCGA-DX-AB2S, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 54.0 years (19,708 days).
Specimen TCGA-DX-AB2S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.a139efd7-21fd-44dc-8355-023e36b2914a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/01242a73-a0e4-4a62-9669-c28de68d58a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 59,346; copy number 3: 7; copy number 4: 63; copy number 5: 144; copy number 6: 142; copy number 7: 35; copy number 8: 1; copy number 9: 22; copy number 10: 20; copy number 11: 1; copy number 12: 11; copy number 13: 11; copy number 14: 17.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 404 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,487,364–150,881,683, 24 genes, copy number 6: TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6.
- chr1:155,562,042–155,739,010, 11 genes, copy number 5 (within-gene range 2–5): ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5, YY1AP1, DAP3, AL162734.1.
- chr1:161,039,251–161,118,055, 6 genes, copy number 6 (within-gene range 2–6): USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2.
- chr1:169,132,531–172,418,466, 71 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:172,532,349–174,022,985, 36 genes, copy number 5–13 (within-gene range 2–14): SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1, TNFSF4, AL645568.2, AL645568.1, PRDX6-AS1, PRDX6, SLC9C2, AL139142.1, AL139142.2, ANKRD45, TEX50, KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776.
- chr12:50,923,472–51,028,566, 7 genes, copy number 6 (within-gene range 2–6): METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2.
- chr12:55,247,198–56,340,410, 87 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr12:57,869,834–57,984,761, 7 genes, copy number 12: AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:58,094,914–59,064,238, 9 genes, copy number 5–7 (within-gene range 3–7): AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22.
- chr12:59,586,793–60,419,293, 10 genes, copy number 5–7: RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr12:65,824,460–65,966,291, 4 genes, copy number 12: HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:68,674,371–68,850,686, 10 genes, copy number 14: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:69,470,349–69,584,823, 3 genes, copy number 5: FRS2, MIR3913-1, MIR3913-2.
- chr12:69,901,918–71,118,247, 17 genes, copy number 6–13 (within-gene range 2–13): PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr12:72,431,722–72,432,075, 1 gene, copy number 11: H3P35.
- chr12:77,129,178–78,213,010, 7 genes, copy number 6 (within-gene range 2–6): AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1.
- chr12:80,936,414–81,759,553, 7 genes, copy number 5 (within-gene range 2–5): ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1.
- chr12:82,223,681–87,170,429, 33 genes, copy number 5–9: CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.3, AC090679.2, AC090679.1, AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68.
- chr12:89,010,681–90,100,763, 24 genes, copy number 7 (within-gene range 2–7): LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399.
- chr12:91,984,976–92,226,557, 7 genes, copy number 7 (within-gene range 2–7): LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA.
- chr12:95,551,582–96,400,480, 23 genes, copy number 10–14 (within-gene range 2–14): PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
